Gene-level copy-number profile of tumor specimen C3N-00836-02 from CPTAC case C3N-00836, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 75.3 years (27,509 days).
Specimen C3N-00836-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 897096e9-b7bf-4fb9-94cb-3d5beec7ab00.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00836-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/8ce540f8-0230-4c52-986f-6fba9bfd7ed6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 10; copy number 2: 58,171; copy number 3: 198; copy number 4: 5; copy number 5: 20.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 20 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:16,197,854–16,212,652, 2 genes, copy number 5: ARHGEF19-AS1, ARHGEF19.
- chr19:16,479,067–16,628,204, 1 gene, copy number 5 (within-gene range 4–5): AC008764.1.
- chr19:16,549,831–16,817,963, 17 genes, copy number 5 (within-gene range 3–5): SLC35E1, AC008764.3, AC008764.5, AC008764.8, MED26, AC008764.4, AC008764.7, AC008764.9, AC008764.10, AC008764.2, AC024075.3, SMIM7, AC024075.2, AC024075.1, TMEM38A, AC008737.2, NWD1.

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
